Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4985, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4985-01A (Primary Tumor).

[page 1 of 5]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA-BP-4985

Clinical Diagnosis & History:

with left renal mass; h/o chordoma.

Specimens Submitted:

- 1: SP: Kidney and adrenal gland, left, radical nephrectomy
- 2: SP: Lymph nodes, para-aortic, excision
- 3: SP: Lymph nodes, suprarenal, excision
- 4: SP: Lymph nodes, intraaortic, excision

DIAGNOSIS:

1. SP: Kidney and adrenal gland, left, radical nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 12.0 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild interstitial fibrosis and tubular atrophy

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

2. SP: Lymph nodes, para-aortic, excision

Lymph Nodes:

[page 2 of 5]
Not involved
Number of nodes examined:13

3. SP: Lymph nodes, supra hilar, excision

Lymph Nodes:
Not involved
Number of nodes examined:6

4. SP: Lymph nodes, Interaorticaval, excision

Lymph Nodes:
Not involved
Number of nodes examined:3

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CHR	
	SYN	
	CHR	
	SYN	
	NEG CONT	
	NEG CONT	
	IMM RECUT	
	IMM RECUT	

Gross Description:

1.) The specimen is received fresh labeled "left adrenal and kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 983 g in total. The kidney measures 14.0 x 10.5 x 7.0 cm. The attached ureter measures 6.5 cm in length and 0.3 cm in diameter. The attached renal vein measures 8.0 cm in length and 0.7 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 6.0 x 2.5 x 1.0 cm. Sectioning through the adrenal gland reveals central hemorrhage. The specimen is inked black posteriorly and anteriorly, and bivalved to reveal a lobulated golden yellow solid and cystic tumor, with multiple fibrous bands, areas of hemorrhage and necrosis, measuring 12.0 x 9.5 x 7.0 cm. The tumor extensively involves the renal sinus and hilar fat. The tumor penetrates through the renal capsule into perirenal fat. The tumor extends to within 0.2 cm of Gerota's fascia. Extension of tumor into the renal vein is not identified. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 1.0 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor
TCF - tumor penetrating renal capsule into perirenal fat
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
TPM - tumor in relation to posterior margin
TGF - tumor in relation to Gerota's fascia
TK -- tumor with adjacent kidney

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Not involved
Number of nodes examined:13

3. SP: Lymph nodes, supra hilar, excision

Lymph Nodes:
Not involved
Number of nodes examined:6

4. SP: Lymph nodes, Interaortacaval, excision

Lymph Nodes:
Not involved
Number of nodes examined:3

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CHR	
	SYN	
	CHR	
	SYN	
	NEG CONT	
	NEG CONT	
	IMM RECUT	
	IMM RECUT	

Gross Description:

1.) The specimen is received fresh labeled "left adrenal and kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 983 g in total. The kidney measures 14.0 x 10.5 x 7.0 cm. The attached ureter measures 6.5 cm in length and 0.3 cm in diameter. The attached renal vein measures 8.0 cm in length and 0.7 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 6.0 x 2.5 x 1.0 cm. Sectioning through the adrenal gland reveals central hemorrhage. The specimen is inked black posteriorly and anteriorly, and bivalved to reveal a lobulated golden yellow solid and cystic tumor, with multiple fibrous bands, areas of hemorrhage and necrosis, measuring 12.0 x 9.5 x 7.0 cm. The tumor extensively involves the renal sinus and hilar fat. The tumor penetrates through the renal capsule into perirenal fat. The tumor extends to within 0.2 cm of Gerota's fascia. Extension of tumor into the renal vein is not identified. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 1.0 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor
TCF - tumor penetrating renal capsule into perirenal fat
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
TPM - tumor in relation to posterior margin
TGF - tumor in relation to Gerota's fascia
TK -- tumor with adjacent kidney

[page 4 of 5]
RP -- renal pelvis representative sections
K -- representative sections kidney
AD -- adrenal gland

2). The specimen is received in formalin, labeled "Para-aortic lymph node" and consists of 11 possible lymph nodes ranging from 0.1 to 1.7 cm in greatest dimension. All possible lymph nodes are submitted.

Summary of sections:
LN-lymph nodes submitted whole
BLN -- bisected lymph node

3). The specimen is received in formalin, labeled "Suprahilar lymph node" and consists of two possible lymph nodes measuring 0.2 and 0.4 cm in greatest dimension with attached hemorrhagic rough tan soft tissue. The specimen is entirely submitted.

Summary of sections:
U-undesignated

4). The specimen is received in formalin, labeled "Intra-aortic lymph node" and consists of three fatty appearing lymph nodes ranging from 0.3 to 1.3 cm in greatest dimension, which are entirely submitted.

Summary of sections:
LN-lymph nodes submitted whole
BLN1 -- bisected lymph node number one
BLN2 -- bisected lymph node number two

Summary of Sections:

Part 1: SP: Kidney and adrenal gland, left, radical nephrectomy

Block	Sect. Site	PCs
1	AD	1
1	K	1
2	RP	2
2	T	2
1	TCF	1
1	TGF	1
1	THF	1
1	TK	1
1	TPM	1
2	TSF	2
1	UVM	1

Part 2: SP: Lymph nodes, para-aortic, excision

Block	Sect. Site	PCs
1	bln	1
3	ln	3

Part 3: SP: Lymph nodes, suprahilar, excision

Block	Sect. Site	PCs
1	u	1

Part 4: SP: Lymph nodes, Intra-aortic, excision

Block	Sect. Site	PCs
-------	------------	-----

[page 5 of 5]
1	bln1	1
1	bln2	1
1	u	1

Source: NCI Genomic Data Commons file 45f5f1b8-e5d7-4e35-942c-350747b166a3 (TCGA-BP-4985.64B339F4-84DB-4BC1-A40E-06DE7F9A60B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).